MMRF case MMRF_2365 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/59873ab0-7a19-4616-87d4-f9f515a73265

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 77 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 77.6 years (28,352 days); ISS stage: III; Days to last known disease status: 165 days; Days to last follow up: 165 days.
   Treatment given: Therapeutic agents: Bortezomib + Melphalan + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -15 (ECOG 1): M Protein 4.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 31.6 mg/dL; Immunoglobulin G 42.2 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 7.26 µg/mL; Hemoglobin 6.32 mmol/L; Leukocytes 7.55 ×10⁹/L; Absolute Neutrophil 3.83 ×10⁹/L; Platelets 426 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 1.82 mmol/L; Calcium 2 mmol/L; Albumin 17.3 g/L; Total Protein 8.58 g/dL; Glucose 5.78 mmol/L; C-Reactive Protein 22.1 mg/dL.
- Day 76 (ECOG 2): M Protein 3.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 17.5 mg/dL; Immunoglobulin G 40.6 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 7.21 µg/mL; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 2.24 ×10⁹/L; Absolute Neutrophil 0.77 ×10⁹/L; Platelets 54.6 ×10⁹/L; Creatinine 55.7 µmol/L; Calcium 1.85 mmol/L; Albumin 23.2 g/L; Total Protein 6.21 g/dL; Glucose 5.56 mmol/L.
- Day 165 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 1.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 15.1 mg/dL; Immunoglobulin G 26.5 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.19 g/L; Hemoglobin 5.51 mmol/L; Leukocytes 3.29 ×10⁹/L; Absolute Neutrophil 1.68 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 71.6 µmol/L; Calcium 2.03 mmol/L; Albumin 29.1 g/L.

Other clinical attributes
- Day -15: Weight: 56 kg; Height: 141 cm.

Biospecimens (2 samples)
- Sample MMRF_2365_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -15 days.
- Sample MMRF_2365_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -15 days.
